Surgical pathology report (de-identified scan), TCGA case TCGA-QL-A97D, project TCGA-COAD (Colon Adenocarcinoma), tissue source site  University of Chicago, specimen TCGA-QL-A97D-01A (Primary Tumor).

[page 1 of 3]
Sample #

FINAL PATHOLOGIC DIAGNOSIS

Right hemicolectomy; ileum, right colon, transverse colon, omentum and lymph node:

- Invasive colonic adenocarcinoma, low grade (see parameters).
- Thirteen lymph nodes, negative for carcinoma (0/13).
- Tubular adenoma (0.7 cm) and tubulovillous adenoma (1.7 cm).
- Small bowel without diagnostic abnormality.

COLON: Resection

Specimen (select all that apply)

Terminal ileum

Cecum

Appendix

Ascending colon

Transverse colon

ICD-O-3
Adenocarcinoma NOS 8140/3
Site ^{CHF} Ascending colon C18.2
^{path} Cecum C18.0
Q1 4/28/14

Procedure: Right hemicolectomy

*Specimen Length

*Specify: 74 cm

Tumor Site: Cecum and ileum

Tumor Size: Greatest dimension: 7.5 cm

Additional dimensions: 5.3 x 4.5 cm

*Block for potential molecular markers: (specify) A8

Macroscopic Tumor Perforation: Not identified

Macroscopic Intactness of Mesorectum: Not applicable

Histologic Type: Adenocarcinoma

Histologic Grade: Low-grade (well-differentiated to moderately differentiated)

Microscopic Tumor Extension: Tumor invades muscularis propria

Margins

Proximal Margin: Uninvolved by invasive carcinoma

Distal Margin: Uninvolved by invasive carcinoma

[page 2 of 3]
Circumferential (Radial) or Mesenteric Margin
Uninvolved by invasive carcinoma

If all margins uninvolved by invasive carcinoma:
Distance of invasive carcinoma from closest margin: 8 mm (A4)
Specify margin: Mesenteric

Treatment Effect (applicable to carcinomas treated with neoadjuvant therapy):
No prior treatment

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Tumor Deposits (discontinuous extramural extension): Not identified

Pathologic Staging (pTNM) pT2, N0

Primary Tumor (pT) pT2: Tumor invades muscularis propria

Regional Lymph Nodes (pN) pN0: No regional lymph node metastasis
Specify: Number examined: 13
Number involved: 0 (Zero out of thirteen)

Distant Metastasis (pM) Not applicable

Additional Pathologic Findings: Adenoma(s): Tubular adenoma (0.7 cm) a
tubulovillous adenoma (1.7 cm)

Clinical History:
The patient is an -year-old female with colon cancer undergoing right
hemicolectomy.

Specimens Received:
A: Ileum, right colon, transverse colon, omentum and lymph node

Gross Description:
A. The specimen is received in a single container labeled with the patient's
name, medical record number, and additionally identified as, 'ileum, right

[page 3 of 3]
colon, transverse colon, omentum and lymph node'. Received fresh and placed in formalin is a hemicolectomy specimen composed of a 44 cm long and 3.2 cm circumference segment of ileum attached to a 30 cm long and 8.3 cm circumference segment of large bowel. There is a palpable mass in the cecum; the serosal surface overlying this palpable mass is adherent to the serosal surface of the transverse colon, forming a loop of large bowel.

The bowel is opened to reveal a partially fungating cecal mass, measuring 7.5 x 4.5 cm, which tunnels inward to a maximal extent of 5.3 cm, extending 3 cm into the ileum. The mucosal surface of the adherent transverse colon is retracted toward the mass but appears intact. The mass is located 25 cm from the proximal resection margin, 3 cm from the distal resection margin, and 1.0 cm from the apparent mesenteric margin. The serosa overlying the mass is inked black; the mesenteric margin is inked red. On sectioning, the mass abuts the black inked margin and does not invade into the wall of the adherent transverse colon.

The remaining mucosa demonstrates two nearby cecal polyps, measuring 0.7 and 1.7 cm in greatest dimension. The pericolonic adipose tissue is dissected for lymph node candidates. Multiple lymph node candidates are identified. Appendix is not identified. Additionally submitted with this specimen is a separate segment of unoriented small bowel measuring 19 cm in length by 3.3 cm in internal circumference; it is grossly unremarkable.

Block summary:

- A1: Proximal resection margin
- A2: Distal resection margin
- A3-A4: Mass closest approach to mesenteric margin
- A5: Mass relationship to transverse colon
- A6-A10 Multiple blocks of mass
- A11: Smaller polyp
- A12: Larger polyp
- A13: 4 lymph node candidates
- A14: 4 lymph nodes
- A15: 2 lymph nodes
- A16-A19: One lymph node in each cassette

Pathologist Sign Out:

Source: NCI Genomic Data Commons file 3ff3b052-2c57-4982-9ca6-bb04bcf27e30 (TCGA-QL-A97D.0433BF3F-FF22-4389-AEFF-60B092A69D88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).